TCGA case TCGA-GV-A40E — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: BLN - Cleveland Clinic. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/aa6142af-bad7-493c-98a0-fd070de39073

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 75 years; Vital status: Dead; Days to death: 261 days.

Diagnoses (5)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 75.5 years (27,569 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Gemcitabine Hydrochloride; Days to treatment start: 56 days; Days to treatment end: 98 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 231 days; Days to treatment end: 244 days; Treatment dose: 3,000 cGy; Treatment outcome: Progressive Disease; Number of fractions: 10; Treatment anatomic sites: Distant Site.
2. Papillary transitional cell carcinoma: ICD-O-3 morphology code: 8130/3; Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary; Age at diagnosis: 75.5 years (27,569 days); AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 0 days; Treatment anatomic sites: Bladder.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Papillary transitional cell carcinoma, non-invasive: Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Surgery, NOS; Timepoint category: Prior to Procurement.
4. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Lung, NOS. Age at diagnosis: 76.1 years (27,788 days); Days to diagnosis: 219 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.
5. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Brain, NOS. Age at diagnosis: 76.1 years (27,796 days); Days to diagnosis: 227 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (5 entries)
- Days to follow up: 195 days; Disease response: Tumor Free.
- Day 219 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 219 days.
- Day 227 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 227 days.
- Days to follow up: 261 days; Disease response: With Tumor.
- Karnofsky performance status: 80.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 115 kg; Height: 178 cm; BMI: 36.3.

Exposures
- Chemical exposure type: Chemical Exposure, NOS.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 20; Tobacco smoking quit year: 1975; Age at onset: 9.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-GV-A40E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 140 mg.
  Slide TCGA-GV-A40E-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-GV-A40E-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-GV-A40E-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Occupation current: retired; Tobacco smoking history indicator: 3; Tobacco smoking age started: 9; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Dome; Anatomic organ subdivision: Trigone; Anatomic organ subdivision: Wall Anterior; Anatomic organ subdivision: Wall Lateral; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: No; Treatment outcome first course: Stable Disease.
- History non muscle invasive blca: Noninvasive bladder history: Yes; Noninvasive bladder CA treatment type: Transurethral resection alone.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Stable Disease.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Drug treatment 2: Pharmaceutical therapy drug name: Gemzar; Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy histological type: Papillary Urothelial Carcinoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Turbt.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Patient had a prior non-muscle invasive bladder cancer. No radiation or systemic chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 261 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 261 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 219 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-GV-A40E-01A-12D-A23L-01): tumor purity 0.34, ploidy 5.52, whole-genome doublings 2.
